Somatic mutation profile of tumor specimen TCGA-5P-A9KC-01A (aliquot TCGA-5P-A9KC-01A-11D-A42J-10) from TCGA case TCGA-5P-A9KC, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 52.0 years (18,975 days).
Specimen TCGA-5P-A9KC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27780486-417e-4438-a2a4-270d62eeecfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9KC-10A (Blood Derived Normal), aliquot TCGA-5P-A9KC-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ee68306-c3b6-40d2-8c6d-2c9d83bdc811

The open-access MAF lists 82 somatic variants for this specimen: 71 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 10, Frame Shift Del 8, Nonsense Mutation 3, Splice Site 2, Frame Shift Ins 1, Nonstop Mutation 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACLY | c.845G>T p.G282V | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100709609; called by muse, mutect2, varscan2
- ADAMTS20 | c.5410A>G p.K1804E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101239116; called by muse, mutect2, varscan2
- ASCL4 | c.310C>A p.L104M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV100661165; called by muse, mutect2, varscan2
- ATXN1 | c.525G>C p.E175D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as COSV99785856; called by muse, mutect2, varscan2
- BNIP5 | c.1419C>G p.S473R | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs1212478548, COSV101465133; called by muse, mutect2, varscan2
- BRCA1 | c.707C>G p.T236S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.096); catalogued as rs80356990, COSV100523698, COSV58803031; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAMK1G | c.338G>C p.G113A | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99151655; called by muse, mutect2, varscan2
- CARF | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1037500785, COSV100247583; called by muse, mutect2, varscan2
- CEP250 | c.2162A>G p.E721G | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV100698849; called by muse, mutect2, varscan2
- CFLAR | c.1286A>G p.Q429R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100009199; called by muse, mutect2, varscan2
- CHAD | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99366114; called by muse, mutect2, varscan2
- CHRNA4 | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100937385; called by muse, mutect2, varscan2
- CIB4 | c.489G>C p.E163D | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99994713; called by muse, mutect2, varscan2
- CLUL1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.93); PolyPhen benign (0.009); catalogued as rs906123764, COSV58113224; called by muse, mutect2, varscan2
- CNTN5 | c.1234A>T p.K412* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV99675161; called by muse, mutect2, varscan2
- CNTNAP5 | c.1744T>A p.C582S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101443289; called by muse, mutect2, varscan2
- COPA | c.2101G>A p.D701N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as COSV99615151; called by muse, mutect2, varscan2
- EMILIN2 | c.3050G>T p.G1017V | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99598357; called by muse, mutect2, varscan2
- ERBB3 | c.732T>C p.F244= | Splice Region (SNP) | VAF 42/85 reads (49%) | catalogued as COSV99916378; called by muse, mutect2, varscan2
- FASTKD3 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV99241521; called by muse, mutect2, varscan2
- HBP1 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 58/125 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs754955216, COSV99753128; called by muse, mutect2, varscan2
- HCRTR2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100904250, COSV63796285; called by muse, mutect2, varscan2
- HP1BP3 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs1229685054, COSV100391698; called by muse, mutect2, varscan2
- KIF26B | c.4012G>A p.D1338N | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs775799993, COSV100831974; called by muse, mutect2, varscan2
- LPIN1 | c.2354del p.N785Tfs*27 | Frame Shift Del (DEL) | VAF 34/114 reads (30%) | catalogued as COSV56763308; called by mutect2, pindel, varscan2
- LPL | c.202C>T p.H68Y | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as rs1022834122, COSV100255462; called by muse, mutect2, varscan2
- LZTR1 | c.644G>T p.W215L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV99301540; called by muse, mutect2, varscan2
- MPP1 | c.1280C>G p.A427G | Missense Mutation (SNP) | VAF 48/174 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101053883; called by muse, mutect2, varscan2
- NFYA | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100399612; called by muse, mutect2, varscan2
- NPAP1 | c.3467C>G p.P1156R | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV100275055, COSV61505445, COSV61511213; called by muse, mutect2, varscan2
- OR5P3 | c.718A>G p.T240A | Missense Mutation (SNP) | VAF 35/125 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103086, COSV60429866, COSV60430222; called by muse, mutect2, varscan2
- OR8B8 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100044956; called by muse, mutect2, varscan2
- PARP4 | c.4004G>A p.S1335N | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV101131438; called by muse, mutect2, varscan2
- PDCD6 | c.248G>C p.S83T | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1560860970, COSV99372649; called by muse, mutect2, varscan2
- PEBP4 | c.166A>T p.I56F | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as COSV99834774; called by muse, mutect2, varscan2
- PFKP | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV101127113; called by muse, mutect2, varscan2
- PFN1 | c.248A>T p.E83V | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV99337287; called by muse, mutect2, varscan2
- POLR3A | c.3713C>G p.T1238R | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100965594; called by muse, mutect2, varscan2
- PSMD4 | c.632G>T p.S211I | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100924655; called by muse, mutect2, varscan2
- PUM2 | c.1514A>G p.Q505R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100163415; called by muse, mutect2, varscan2
- R3HDM2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV61297287; called by muse, mutect2, varscan2
- RAB6B | c.402-1G>A p.X134_splice | Splice Site (SNP) | VAF 17/52 reads (33%) | catalogued as COSV99557899; called by muse, mutect2, varscan2
- RAF1 | c.513A>T p.K171N | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99312247; called by muse, mutect2, varscan2
- RHOU | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.431); catalogued as COSV64208492; called by muse, mutect2, varscan2
- SAMD15 | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 56/189 reads (30%) | catalogued as COSV99374879; called by muse, mutect2, varscan2
- SASH1 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs1562477841, COSV100821081; called by muse, mutect2, varscan2
- SCAMP2 | c.31G>A p.D11N | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV99173935; called by muse, mutect2, varscan2
- SCAPER | c.4031T>A p.L1344Q | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100237833; called by muse, mutect2, varscan2
- SENP6 | c.1999T>G p.S667A | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100519079; called by muse, mutect2, varscan2
- SMG7 | c.3224G>A p.S1075N | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.024); catalogued as rs750689856, COSV100750162; called by muse, mutect2, varscan2
- SYT16 | c.1379A>G p.H460R | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as COSV101413547; called by muse, mutect2, varscan2
- TFPI2 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 91/199 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55991563, COSV99746662; called by muse, mutect2, varscan2
- TMEM176B | c.292T>C p.C98R | Missense Mutation (SNP) | VAF 46/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100423516; called by muse, mutect2
- TRIM44 | c.565T>A p.Y189N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV100194906; called by muse, mutect2, varscan2
- TRIM49 | c.412-1G>A p.X138_splice | Splice Site (SNP) | VAF 28/177 reads (16%) | catalogued as COSV100315967; called by muse, mutect2, varscan2
- TTC7B | c.706A>G p.T236A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.931); catalogued as COSV100127669; called by muse, mutect2, varscan2
- TUBB8 | c.383A>G p.D128G | Missense Mutation (SNP) | VAF 6/175 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.927); catalogued as COSV100225998; called by muse, mutect2
- UBR3 | c.4444T>C p.S1482P | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV99773730; called by muse, mutect2, varscan2
- ZDHHC23 | c.668G>C p.G223A | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.699); catalogued as rs780185376, COSV100362093; called by muse, mutect2, varscan2
- ZFP82 | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV101088974; called by muse, mutect2, varscan2
- ZNF250 | c.1618T>C p.C540R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1354842528, COSV99480772; called by muse, mutect2, varscan2
- AHNAK | c.7353del p.N2452Ifs*9 | Frame Shift Del (DEL) | VAF 31/120 reads (26%) | called by mutect2, pindel, varscan2
- ELOVL6 | c.238_239del p.R80Nfs*20 | Frame Shift Del (DEL) | VAF 34/171 reads (20%) | called by mutect2, pindel, varscan2
- GDAP2 | c.1354dup p.I452Nfs*20 | Frame Shift Ins (INS) | VAF 45/162 reads (28%) | called by mutect2, pindel, varscan2
- ITGB3 | c.2084dup p.Y695* | Nonsense Mutation (INS) | VAF 25/94 reads (27%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.4654_4670del p.L1552Rfs*26 | Frame Shift Del (DEL) | VAF 9/76 reads (12%) | called by pindel, varscan2
- RIC1 | c.2315del p.F772Sfs*8 | Frame Shift Del (DEL) | VAF 38/140 reads (27%) | called by mutect2, pindel, varscan2
- SMARCB1 | c.814_815del p.Q272Afs*42 (on ENST00000263121; = p.Q318Afs*42 on NM_003073.5) | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- TMEM170B | c.397_*5del | Nonstop Mutation (DEL) | VAF 9/69 reads (13%) | called by mutect2, pindel, varscan2
- ZMYND10 | c.162_172del p.Q54Hfs*71 | Frame Shift Del (DEL) | VAF 16/52 reads (31%) | called by pindel, varscan2*
- ZNF226 | c.173del p.P58Lfs*2 | Frame Shift Del (DEL) | VAF 71/287 reads (25%) | called by mutect2, pindel, varscan2
- CNNM1 | c.1149G>C p.A383= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV100763809, COSV63201890, COSV63204000; called by muse, mutect2, varscan2
- COL8A2 | c.954A>C p.P318= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100291079; called by muse, mutect2, varscan2
- DDN | c.582A>T p.G194= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100305017; called by muse, mutect2, varscan2
- FOXC1 | c.531G>A p.K177= | Silent (SNP) | VAF 168/633 reads (27%) | catalogued as rs922369652, COSV101083264; called by muse, mutect2, varscan2
- FYB1 | c.1263C>A p.P421= | Silent (SNP) | VAF 52/181 reads (29%) | catalogued as COSV100685165, COSV100685284; called by muse, mutect2, varscan2
- KMT5B | c.1290T>G p.T430= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100430046; called by muse, mutect2, varscan2
- RACK1 | c.33C>G p.L11= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as COSV100958669, COSV100958831; called by muse, mutect2, varscan2
- SMAP1 | c.567A>G p.T189= (on ENST00000370455 / NM_001044305.3; = p.T162= on NM_021940.5) | Silent (SNP) | VAF 289/1133 reads (26%) | catalogued as COSV100391016; called by muse, mutect2, varscan2
- SNX17 | c.378G>C p.G126= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV99277438; called by muse, mutect2, varscan2
- TGDS | c.675A>G p.S225= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as COSV99725043; called by muse, mutect2, varscan2
- ITCH | c.1548-3702T>G | Intron (SNP) | VAF 11/45 reads (24%) | catalogued as COSV99392229; called by muse, mutect2, varscan2
